Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90P, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A90P-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

ICD O-3
Carcinoma, embryonal NOS
Site O Testis NOS
907013
C62.9
JW 3/3/14

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

Left testis: 100% pure TSS,
Embryonal carcinoma with uninvolved margins.
Albuginea uninvolved by neoplasia.
Absence of angiolymphatic and sanguineous invasions.

Left epididymis:
Absence of neoplasia.

Spermatic cord uninvolved by neoplasia.

Criteria	JW - 1/2/14	Yes	No
Diagnosis Discrepancy	100% to embryonal	✓	✓
ICD/A Discrepancy		✓	✓
Non-Malignancy History		✓	✓
Metastatic/Synchronous Primary Noted		✓	✓
Reviewer Initials	MA	Site Reviewed	1/3/13

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Embryonal Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	100% Embryonal Adenocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case was reviewed based on Top Slide to be sent to BCR	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 7ef91085-88ab-4092-bd0d-28e977c1eb76 (TCGA-YU-A90P.D52051CD-DEC1-4431-8717-7DB7927CD70D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).